Somatic mutation profile of tumor specimen TCGA-29-1770-01A (aliquot TCGA-29-1770-01A-01W-0633-09) from TCGA case TCGA-29-1770, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 54.8 years (20,015 days).
Specimen TCGA-29-1770-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4262f17-d047-44c6-9f6a-eeb545f6cf73.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-29-1770-10A (Blood Derived Normal), aliquot TCGA-29-1770-10A-01W-0634-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/72c183b5-4e61-4f43-84d5-7c88d38798bf

The open-access MAF lists 105 somatic variants for this specimen: 73 protein-altering or splice-affecting, 28 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 28, Nonsense Mutation 7, Frame Shift Ins 5, Frame Shift Del 4, RNA 4, In Frame Ins 1, Splice Site 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 34/57 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TREX1 | c.144dup p.T49Hfs*53 (on ENST00000625293 / NM_033629.6; = p.T39Hfs*53 on NM_007248.5) | Frame Shift Ins (INS) | VAF 10/60 reads (17%) | catalogued as rs748914604; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- AP002512.3 | c.1126A>T p.M376L | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV99687812; called by muse, mutect2
- APOB | c.9358G>T p.E3120* | Nonsense Mutation (SNP) | VAF 8/105 reads (8%) | catalogued as COSV99264350; called by muse, mutect2
- ATAD2 | c.2689G>C p.D897H | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV54877146; called by muse, mutect2, varscan2
- BCORL1 | c.2702C>T p.P901L | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as COSV54389343; called by muse, mutect2, varscan2
- BPIFB3 | c.1418_1429del p.T473_*477delinsR | Nonstop Mutation (DEL) | VAF 57/211 reads (27%) | catalogued as COSV64956748; called by mutect2, pindel, varscan2
- CDCA8 | c.366G>T p.M122I | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV59237852; called by muse, mutect2, varscan2
- CHRD | c.2756C>A p.S919Y | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV52605318; called by muse, mutect2, varscan2
- CNGB1 | c.221C>A p.T74N | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.782); catalogued as COSV99202122; called by muse, mutect2
- COX8C | c.181T>C p.Y61H | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1157788430, COSV56373276; called by muse, mutect2, varscan2
- CSF1R | c.2503C>T p.Q835* | Nonsense Mutation (SNP) | VAF 30/187 reads (16%) | catalogued as rs1403823146, COSV53828205; called by muse, mutect2
- CSMD3 | c.10172G>A p.R3391H (on ENST00000297405 / NM_001363185.1; = p.R3222H on NM_052900.3) | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs750171856, COSV52100044, COSV52183749; called by muse, mutect2, varscan2
- CSMD3 | c.8955A>T p.K2985N (on ENST00000297405 / NM_001363185.1; = p.K2816N on NM_052900.3) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as COSV99828261; called by muse, mutect2
- CYP4F2 | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV99171050; called by muse, mutect2
- DAB1 | c.1618G>T p.D540Y (on ENST00000371231; = p.D507Y on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV64690058, COSV64690164; called by muse, mutect2, varscan2
- DHX16 | c.2550C>A p.N850K | Missense Mutation (SNP) | VAF 24/278 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV99527792; called by muse, varscan2
- E2F5 | c.709A>T p.K237* | Nonsense Mutation (SNP) | VAF 13/89 reads (15%) | catalogued as COSV56273976; called by muse, mutect2, varscan2
- EGFLAM | c.1308T>A p.D436E | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59293060; called by muse, mutect2, varscan2
- ELAPOR2 | c.2725A>T p.K909* (on ENST00000450689 / NM_001142749.3; = p.K742* on NM_152748.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | catalogued as COSV51883873, COSV51886981; called by muse, mutect2, varscan2
- ESR2 | c.652G>T p.G218C | Missense Mutation (SNP) | VAF 53/105 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV50828508; called by muse, mutect2, varscan2
- FARSA | c.1388+2T>A p.X463_splice | Splice Site (SNP) | VAF 36/73 reads (49%) | catalogued as COSV53365423; called by muse, mutect2, varscan2
- IFT140 | c.1411G>C p.G471R | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV68485820; called by muse, mutect2, varscan2
- ITGB2 | c.884G>T p.R295M | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100185709; called by muse, mutect2
- LTBP4 | c.3766G>A p.E1256K (on ENST00000308370 / NM_001042544.1; = p.E1219K on NM_003573.2) | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as rs754736184, COSV52575963, COSV52583546; called by muse, mutect2
- MAN1C1 | c.1097T>A p.L366H | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99847960; called by muse, mutect2
- MAP3K13 | c.967G>T p.E323* | Nonsense Mutation (SNP) | VAF 33/49 reads (67%) | catalogued as COSV53983368, COSV53993277; called by muse, mutect2, varscan2
- MBD6 | c.2104dup p.Q702Pfs*15 | Frame Shift Ins (INS) | VAF 4/29 reads (14%) | catalogued as rs756309560; called by pindel, varscan2
- MYO9A | c.5895G>A p.M1965I | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.104); catalogued as COSV61847483; called by muse, mutect2, varscan2
- NLRP3 | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV60219626; called by muse, mutect2, varscan2
- NOL4L | c.314C>T p.S105F | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.371); catalogued as COSV62889051; called by muse, mutect2, varscan2
- NPRL2 | c.481G>C p.E161Q | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.011); catalogued as COSV51603093; called by muse, mutect2
- PIGG | c.2401T>G p.L801V (on ENST00000453061 / NM_001127178.3; = p.L793V on NM_017733.4) | Missense Mutation (SNP) | VAF 24/217 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.072); catalogued as COSV56316076; called by muse, mutect2
- PIK3CB | c.10A>T p.S4C | Missense Mutation (SNP) | VAF 120/237 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV100005385, COSV56683279; called by muse, mutect2, varscan2
- PMS2 | c.2248G>T p.G750C | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56219547; called by muse, mutect2, varscan2
- PPP4R4 | c.1526A>T p.K509I | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as COSV58551644, COSV58555022; called by muse, mutect2, varscan2
- PTCHD4 | c.676T>A p.F226I | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.205); catalogued as COSV59777392; called by muse, mutect2, varscan2
- RGS20 | c.1107G>C p.M369I (on ENST00000297313 / NM_170587.4; = p.M222I on NM_003702.4) | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.055); catalogued as COSV52013831; called by muse, mutect2, varscan2
- RGS22 | c.1183G>C p.E395Q | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV100693071; called by muse, mutect2
- RTL5 | c.1588dup p.Q530Pfs*83 | Frame Shift Ins (INS) | VAF 6/46 reads (13%) | catalogued as rs1474897273; called by mutect2, varscan2
- SEZ6L | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.063); catalogued as rs764095767, COSV50657840; called by muse, mutect2, varscan2
- SIGLEC8 | c.979A>T p.T327S | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV58471779; called by muse, mutect2, varscan2
- SLC27A1 | c.600G>C p.L200F | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.836); catalogued as COSV99393092; called by muse, mutect2
- SNU13 | c.163G>A p.V55M | Missense Mutation (SNP) | VAF 69/187 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV53237787; called by muse, mutect2, varscan2
- SNX7 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.455); catalogued as COSV100068688; called by muse, mutect2
- SPTA1 | c.2427C>G p.I809M | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63748345, COSV63754103; called by muse, mutect2
- SYNE3 | c.1042A>G p.R348G | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); catalogued as COSV100515757; called by muse, mutect2, varscan2
- TBC1D22B | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as COSV65142182; called by muse, varscan2
- TFAP2B | c.1103C>T p.T368M | Missense Mutation (SNP) | VAF 77/198 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as COSV53824970; called by muse, mutect2, varscan2
- TMPPE | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs199657885, COSV56561270; called by muse, mutect2, varscan2
- TNKS1BP1 | c.5105C>T p.P1702L | Missense Mutation (SNP) | VAF 44/352 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64099893; called by muse, mutect2, varscan2
- TRAF1 | c.844G>T p.E282* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as COSV100875122; called by muse, mutect2
- TRRAP | c.2313C>G p.S771R | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100722184; called by muse, mutect2
- TUBAL3 | c.689C>A p.S230Y | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.964); catalogued as COSV66813892; called by muse, mutect2, varscan2
- U2SURP | c.76T>C p.S26P | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.693); catalogued as COSV67529973; called by muse, mutect2, varscan2
- UHRF1BP1L | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99691264; called by muse, mutect2, varscan2
- VPS26C | c.636G>C p.Q212H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV99898356; called by muse, mutect2
- XPC | c.1554G>C p.E518D | Missense Mutation (SNP) | VAF 67/447 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.406); catalogued as COSV53203556; called by muse, varscan2
- XRRA1 | c.1770G>T p.K590N | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV55130421; called by muse, mutect2, varscan2
- ZNF662 | c.434G>T p.G145V | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV60240894; called by muse, mutect2, varscan2
- ZNF74 | c.1150G>A p.G384S | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62620097; called by muse, mutect2, varscan2
- ZNF831 | c.3799A>G p.K1267E | Missense Mutation (SNP) | VAF 96/189 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV64037189; called by muse, mutect2, varscan2
- ZP1 | c.1511G>A p.R504Q | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs370756235; called by muse, mutect2
- FAM135B | c.826del p.A276Pfs*18 | Frame Shift Del (DEL) | VAF 6/65 reads (9%) | called by mutect2, pindel
- FAM81A | c.1102A>C p.M368L | Missense Mutation (SNP) | VAF 2/16 reads (13%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); called by muse, mutect2
- FCGBP | c.6967C>T p.Q2323* | Nonsense Mutation (SNP) | VAF 8/86 reads (9%) | called by muse, mutect2
- FPGT | c.1570_1593delinsTT p.E524Ffs*3 | Frame Shift Del (DEL) | VAF 13/26 reads (50%) | called by pindel, varscan2*
- FRAS1 | c.9108_9110dup p.D3036dup | In Frame Ins (INS) | VAF 14/83 reads (17%) | called by mutect2, varscan2
- MFSD4B | c.60dup p.T21Dfs*404 (on ENST00000368847; = p.D116Gfs*26 on NM_153369.4) | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by pindel, varscan2
- PARP12 | c.1258dup p.S420Ffs*2 | Frame Shift Ins (INS) | VAF 12/112 reads (11%) | called by mutect2, varscan2
- PARVB | c.751del p.D251Ifs*6 | Frame Shift Del (DEL) | VAF 15/99 reads (15%) | called by mutect2, pindel, varscan2
- SIPA1L2 | c.3607G>A p.G1203R | Missense Mutation (SNP) | VAF 20/616 reads (3%) | SIFT tolerated (0.55); PolyPhen benign (0.109); called by muse, mutect2
- STRIP1 | c.1747_1751del p.L583Afs*6 | Frame Shift Del (DEL) | VAF 6/59 reads (10%) | called by mutect2, pindel, varscan2
- AADAC | c.924T>G p.A308= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV51758158; called by muse, mutect2, varscan2
- ACIN1 | c.1587C>T p.L529= | Silent (SNP) | VAF 81/197 reads (41%) | catalogued as rs1355768740, COSV52973135; called by muse, mutect2, varscan2
- ADGRB2 | c.561C>G p.L187= | Silent (SNP) | VAF 2/18 reads (11%) | catalogued as rs867510681; called by muse, mutect2
- AQP10 | c.825T>A p.A275= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as COSV59244670; called by muse, mutect2, varscan2
- ARHGEF15 | c.1275G>T p.V425= | Silent (SNP) | VAF 92/131 reads (70%) | catalogued as COSV62724284, COSV62724566; called by muse, mutect2, varscan2
- AUP1 | c.945C>T p.V315= | Silent (SNP) | VAF 39/189 reads (21%) | catalogued as COSV51206090; called by muse, mutect2, varscan2
- BDKRB2 | c.475C>T p.L159= | Silent (SNP) | VAF 40/150 reads (27%) | catalogued as COSV60013541, COSV60014461; called by muse, varscan2
- CCL14 | c.252G>A p.Q84= (on ENST00000618404 / NM_032963.4; = p.Q100= on NM_032962.4) | Silent (SNP) | VAF 16/136 reads (12%) | called by muse, mutect2
- COL9A2 | c.480G>T p.P160= | Silent (SNP) | VAF 41/126 reads (33%) | catalogued as rs745522018, COSV65607073, COSV65607330; called by muse, mutect2, varscan2
- FCGR1A | c.549C>T p.V183= | Silent (SNP) | VAF 16/341 reads (5%) | catalogued as rs1553751213, COSV100977271; called by muse, mutect2
- MAP3K6 | c.558G>C p.R186= | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as COSV54640454; called by muse, mutect2, varscan2
- MINAR1 | c.2373G>A p.Q791= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs775830765, COSV100548732; called by mutect2, varscan2
- MUC16 | c.12537A>G p.Q4179= | Silent (SNP) | VAF 36/218 reads (17%) | catalogued as COSV67443756; called by muse, mutect2, varscan2
- NOP56 | c.747G>A p.R249= | Silent (SNP) | VAF 9/91 reads (10%) | catalogued as COSV61388880; called by mutect2, varscan2
- OR4N2 | c.205C>T p.L69= | Silent (SNP) | VAF 60/297 reads (20%) | catalogued as COSV100269455; called by muse, mutect2
- OR8I2 | c.840C>T p.V280= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV56166547; called by muse, mutect2, varscan2
- PADI4 | c.453G>A p.L151= | Silent (SNP) | VAF 61/77 reads (79%) | catalogued as COSV64923012; called by muse, mutect2, varscan2
- PSMC3IP | c.549G>C p.L183= (on ENST00000393795 / NM_016556.4; = p.L171= on NM_013290.6) | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as COSV53816050; called by muse, mutect2, varscan2
- RFX3 | c.2160C>T p.L720= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV65858046; called by mutect2, varscan2
- RPS6KB1 | c.258C>A p.I86= | Silent (SNP) | VAF 23/300 reads (8%) | catalogued as COSV99847392; called by muse, mutect2
- SLC23A2 | c.1266A>G p.E422= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV100594888; called by muse, mutect2, varscan2
- TRMO | c.747G>A p.E249= | Silent (SNP) | VAF 18/124 reads (15%) | catalogued as COSV100908865, COSV104426748; called by muse, mutect2, varscan2
- TTC21A | c.1122C>T p.I374= | Silent (SNP) | VAF 11/139 reads (8%) | catalogued as COSV100087113; called by muse, mutect2
- TTN | c.69873A>G p.P23291= (on ENST00000591111; = p.P15867= on NM_003319.4) | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as COSV59880367; called by muse, mutect2, varscan2
- ZC3H12C | c.1560C>G p.S520= | Silent (SNP) | VAF 78/119 reads (66%) | catalogued as COSV53706423; called by muse, mutect2, varscan2
- ZNF160 | c.1935A>G p.G645= | Silent (SNP) | VAF 9/248 reads (4%) | called by muse, mutect2
- ZNF26 | c.1203T>C p.S401= | Silent (SNP) | VAF 4/70 reads (6%) | called by muse, mutect2
- ZNF777 | c.210G>A p.R70= | Silent (SNP) | VAF 16/324 reads (5%) | catalogued as COSV99925048; called by muse, mutect2
- C9orf106 | n.394del | RNA (DEL) | VAF 16/20 reads (80%) | called by mutect2, varscan2
- MIR519E | n.25G>A | RNA (SNP) | VAF 96/546 reads (18%) | catalogued as rs1199021002; called by muse, mutect2, varscan2
- MIR519E | n.26G>A | RNA (SNP) | VAF 88/539 reads (16%) | catalogued as rs1249808405; called by muse, mutect2, varscan2
- SNORD115-18 | n.67G>A | RNA (SNP) | VAF 54/196 reads (28%) | called by muse, mutect2
